Somatic mutation profile of cancer-model specimen HCM-CSHL-0385-C18-85A (3D Organoid; aliquot HCM-CSHL-0385-C18-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0385-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 82.2 years (30,009 days).
Specimen HCM-CSHL-0385-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55e8f7fa-21f4-4364-856f-c5cd35f01083.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0385-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0385-C18-11A-11D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5dde88e-1559-4a13-974a-7e175c21b1a3

The open-access MAF lists 144 somatic variants for this specimen: 90 protein-altering or splice-affecting, 38 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 38, Intron 11, Nonsense Mutation 9, RNA 2, Frame Shift Del 2, 3'UTR 1, Splice Site 1, 5'UTR 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 262/262 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.3808C>T p.R1270* | Nonsense Mutation (SNP) | VAF 99/531 reads (19%) | catalogued as rs575627531, CM095220, COSV66072346; called by muse, mutect2, varscan2
- AMOTL1 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0.01); catalogued as rs371990968; called by muse, varscan2
- ANKFN1 | c.2756G>A p.R919H (on ENST00000653862; = p.R772H on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/176 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as rs534504337; called by muse, mutect2, varscan2
- APC | c.3850G>T p.E1284* | Nonsense Mutation (SNP) | VAF 299/299 reads (100%) | catalogued as COSV57324438, COSV57388721; called by muse, mutect2, varscan2
- APPL2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 114/214 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs768459444; called by muse, mutect2, varscan2
- ARHGAP36 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 278/278 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1288631219, COSV99357401; called by muse, mutect2, varscan2
- ATP2B2 | c.1364C>T p.S455L (on ENST00000352432; = p.S421L on NM_001683.5) | Missense Mutation (SNP) | VAF 157/296 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1198836153, COSV100660404; called by muse, mutect2, varscan2
- AUTS2 | c.2944G>A p.V982M | Missense Mutation (SNP) | VAF 167/560 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769391491; called by muse, mutect2, varscan2
- CBX2 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs782184946; called by muse, mutect2, varscan2
- CFAP70 | c.3133C>T p.R1045W | Missense Mutation (SNP) | VAF 167/335 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs775878004, COSV60288092; called by muse, mutect2, varscan2
- CNPY1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 16/309 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.742); catalogued as rs1344924963, COSV58786479; called by muse, mutect2
- COL6A3 | c.6076G>A p.E2026K | Missense Mutation (SNP) | VAF 99/523 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs770907851, COSV55109826; called by muse, mutect2, varscan2
- CTNND2 | c.1491del p.N498Ifs*58 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as COSV58882979; called by mutect2, pindel, varscan2
- EBF1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768501688, COSV58175661; called by muse, mutect2, varscan2
- EPN1 | c.477G>A p.T159= | Splice Region (SNP) | VAF 144/243 reads (59%) | catalogued as rs1266376356; called by muse, mutect2, varscan2
- ERV3-1 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs935315359; called by muse, mutect2, varscan2
- FAM170B | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 114/229 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1374774215, COSV61254342; called by muse, mutect2, varscan2
- FBXL2 | c.37A>T p.K13* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV52139443; called by muse, mutect2
- FKBP1C | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 190/363 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs746685019; called by muse, mutect2, varscan2
- FMN1 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.07); catalogued as rs532741420; called by muse, mutect2, varscan2
- FREM2 | c.8409+1G>A p.X2803_splice | Splice Site (SNP) | VAF 72/477 reads (15%) | catalogued as rs989161115, COSV54852061; called by muse, mutect2, varscan2
- GALNT5 | c.1562A>G p.N521S | Missense Mutation (SNP) | VAF 135/305 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.583); catalogued as rs779011189; called by muse, mutect2, varscan2
- IGKV3-15 | c.157T>G p.L53V | Missense Mutation (SNP) | VAF 103/755 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as rs768194531; called by muse, mutect2, varscan2
- KIAA0100 | c.5129G>A p.R1710Q | Missense Mutation (SNP) | VAF 114/226 reads (50%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as rs766953031, COSV66491878; called by muse, mutect2, varscan2
- KRT33B | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 93/507 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.746); catalogued as rs773485517, COSV52440636; called by muse, mutect2, varscan2
- MAP4K1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 136/253 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1309678682, COSV67709791; called by muse, mutect2, varscan2
- MRPL1 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 89/172 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs773663338; called by muse, mutect2, varscan2
- MYH9 | c.3913G>A p.A1305T | Missense Mutation (SNP) | VAF 162/322 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs372780340; called by muse, mutect2, varscan2
- NFASC | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 89/169 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs1313443406, COSV100362558; called by muse, mutect2, varscan2
- NOTUM | c.1136C>G p.P379R | Missense Mutation (SNP) | VAF 93/191 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs764419336; called by muse, mutect2, varscan2
- NPR3 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.892); catalogued as COSV54088823; called by muse, mutect2, varscan2
- OR52E8 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs760316487; called by muse, varscan2
- OTOF | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 201/414 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs111033444, COSV99718513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGAM5 | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 101/213 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV58203008; called by muse, mutect2, varscan2
- PLCZ1 | c.1540G>C p.G514R | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56850473; called by muse, mutect2, varscan2
- POLK | c.2350G>A p.V784I | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs754272745; called by muse, mutect2, varscan2
- PTPN21 | c.2777G>A p.R926Q | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60852134; called by muse, mutect2, varscan2
- ROBO1 | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV71391743, COSV71398442, COSV71398684; called by muse, mutect2, varscan2
- RPS19 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 197/310 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as CM004367, CM042768; called by muse, mutect2, varscan2
- RUFY4 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200688740; called by muse, mutect2, varscan2
- SORCS1 | c.433C>G p.R145G | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV53879758; called by muse, mutect2, varscan2
- SPSB4 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 132/269 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs760490073; called by muse, mutect2, varscan2
- STX11 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 147/364 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.072); catalogued as COSV62449231; called by muse, mutect2, varscan2
- TEP1 | c.6046C>G p.L2016V | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as rs375172392, COSV52996717; called by muse, mutect2, varscan2
- TMIGD3 | c.322C>T p.R108* (on ENST00000369717 / NM_001081976.2; = p.R189* on NM_020683.7) | Nonsense Mutation (SNP) | VAF 49/178 reads (28%) | catalogued as rs373256860, COSV63163145; called by muse, mutect2, varscan2
- TNF | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 93/186 reads (50%) | catalogued as COSV69304535; called by muse, mutect2, varscan2
- TRIB2 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 197/432 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770239256; called by muse, mutect2, varscan2
- WDR90 | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 156/330 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV53467038; called by muse, mutect2, varscan2
- ZNF334 | c.988T>C p.F330L | Missense Mutation (SNP) | VAF 161/262 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV61619411; called by muse, mutect2, varscan2
- ZNF423 | c.143G>A p.R48H (on ENST00000563137 / NM_001379286.1; = p.R40H on NM_015069.4) | Missense Mutation (SNP) | VAF 115/231 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.299); catalogued as rs759959155, COSV52191688; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2449C>T p.R817W | Missense Mutation (SNP) | VAF 50/351 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP002512.3 | c.690C>A p.C230* | Nonsense Mutation (SNP) | VAF 34/162 reads (21%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.2824G>A p.V942M | Missense Mutation (SNP) | VAF 102/215 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- BAP1 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 285/603 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- C12orf45 | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- C1QTNF4 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CACNA1E | c.6764C>T p.A2255V (on ENST00000367573 / NM_001205293.3; = p.A2212V on NM_000721.4) | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CECR2 | c.2577C>G p.Y859* (on ENST00000342247 / NM_001290047.2; = p.Y676* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 234/441 reads (53%) | called by muse, mutect2, varscan2
- CIAPIN1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- CMAS | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCHS1 | c.8848G>T p.V2950L | Missense Mutation (SNP) | VAF 189/355 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DDI1 | c.826T>A p.C276S | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH8 | c.10988A>T p.K3663M | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EVC2 | c.1713G>T p.E571D | Missense Mutation (SNP) | VAF 88/219 reads (40%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- FBXL2 | c.39A>T p.K13N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2
- GBF1 | c.2752G>A p.V918M (on ENST00000369983 / NM_001377137.1; = p.V917M on NM_004193.3) | Missense Mutation (SNP) | VAF 104/466 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- GRM8 | c.907T>G p.F303V | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HAUS4 | c.805del p.E269Kfs*7 | Frame Shift Del (DEL) | VAF 53/155 reads (34%) | called by mutect2, pindel, varscan2
- HDAC11 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXC4 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IHH | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- INTS3 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 94/212 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNA6 | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 124/206 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KCNK2 | c.986C>A p.A329D (on ENST00000444842 / NM_001017425.3; = p.A314D on NM_014217.4) | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- KIF1B | c.2557C>T p.R853* (on ENST00000377086 / NM_001365952.1; = p.R807* on NM_015074.3) | Nonsense Mutation (SNP) | VAF 190/412 reads (46%) | called by muse, mutect2, varscan2
- MAPK6 | c.1456A>T p.K486* | Nonsense Mutation (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- NEXMIF | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OBSCN | c.12998A>G p.Q4333R | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PCDHB15 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 136/735 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- PDILT | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 154/248 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- POLR3K | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 112/225 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PRDM2 | c.4951C>T p.R1651W | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLITRK1 | c.1248C>A p.N416K | Missense Mutation (SNP) | VAF 83/656 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SWT1 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 115/194 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM262 | c.65C>A p.A22E (on ENST00000530719 / NM_001282448.1; = p.A20E on NM_001242631.2) | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- TTC3 | c.4668T>G p.I1556M | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- WHRN | c.1031G>A p.R344K | Missense Mutation (SNP) | VAF 116/702 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF17 | c.435G>T p.R145S | Missense Mutation (SNP) | VAF 146/381 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ZNF804B | c.3043A>G p.T1015A | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ADCY10 | c.3369T>G p.S1123= | Silent (SNP) | VAF 174/629 reads (28%) | called by muse, mutect2, varscan2
- AHNAK2 | c.5410C>A p.R1804= | Silent (SNP) | VAF 91/671 reads (14%) | catalogued as rs373634735; called by muse, mutect2, varscan2
- ANHX | c.231G>A p.A77= | Silent (SNP) | VAF 52/188 reads (28%) | catalogued as rs754244307, COSV69293506; called by muse, mutect2
- ANKRD50 | c.1236C>T p.A412= | Silent (SNP) | VAF 47/192 reads (24%) | catalogued as rs144274174; called by muse, mutect2, varscan2
- ARC | c.516C>T p.Y172= | Silent (SNP) | VAF 73/151 reads (48%) | catalogued as rs914174862, COSV100751762; called by muse, mutect2, varscan2
- BAIAP3 | c.2880A>G p.A960= | Silent (SNP) | VAF 123/270 reads (46%) | catalogued as rs764482909; called by muse, mutect2, varscan2
- BCAS3 | c.2529C>T p.F843= (on ENST00000390652 / NM_001353144.2; = p.F828= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as rs1309211320; called by muse, mutect2, varscan2
- CEP164 | c.1431C>T p.H477= | Silent (SNP) | VAF 56/152 reads (37%) | catalogued as rs539441637; called by muse, mutect2, varscan2
- CHST3 | c.486C>T p.F162= | Silent (SNP) | VAF 387/773 reads (50%) | catalogued as rs774188997, COSV64150708; called by muse, mutect2, varscan2
- COL18A1 | c.4146C>T p.P1382= (on ENST00000359759 / NM_130444.3; = p.P1147= on NM_030582.4) | Silent (SNP) | VAF 109/254 reads (43%) | catalogued as rs555990845; called by muse, mutect2, varscan2
- COL18A1 | c.4524C>T p.P1508= (on ENST00000359759 / NM_130444.3; = p.P1273= on NM_030582.4) | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs529776494; called by muse, mutect2, varscan2
- COL1A2 | c.3600C>T p.G1200= | Silent (SNP) | VAF 98/353 reads (28%) | catalogued as rs777362679, COSV51955606, COSV99798646; ClinVar: likely benign; called by muse, varscan2
- COL6A2 | c.2622C>T p.N874= | Silent (SNP) | VAF 323/680 reads (48%) | catalogued as rs138270307; called by muse, mutect2, varscan2
- CORO2A | c.993C>T p.D331= | Silent (SNP) | VAF 125/210 reads (60%) | catalogued as rs1241496233, COSV100674141; called by muse, mutect2, varscan2
- DRD5 | c.912C>A p.V304= | Silent (SNP) | VAF 23/122 reads (19%) | called by muse, mutect2, varscan2
- FAM47B | c.1545C>T p.D515= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as rs1269361889, COSV61452702, COSV61456047; called by muse, mutect2, varscan2
- FOXS1 | c.180C>T p.P60= | Silent (SNP) | VAF 665/1092 reads (61%) | catalogued as rs1046363373, COSV54066626; called by muse, mutect2, varscan2
- HEY2 | c.804C>T p.A268= | Silent (SNP) | VAF 35/154 reads (23%) | catalogued as COSV100856275, COSV64240839; called by muse, mutect2, varscan2
- KCNJ9 | c.732G>A p.P244= | Silent (SNP) | VAF 127/420 reads (30%) | catalogued as COSV63631988; called by muse, mutect2, varscan2
- LHX5 | c.1095C>T p.P365= | Silent (SNP) | VAF 131/267 reads (49%) | catalogued as rs767444561; called by muse, mutect2, varscan2
- MLXIP | c.1443G>A p.P481= | Silent (SNP) | VAF 82/175 reads (47%) | catalogued as rs761317330; called by muse, mutect2, varscan2
- NECAP1 | c.648G>A p.P216= | Silent (SNP) | VAF 13/234 reads (6%) | catalogued as rs370869772; called by muse, mutect2
- NLRP10 | c.1626G>A p.A542= | Silent (SNP) | VAF 75/152 reads (49%) | catalogued as rs778031870, COSV60783192; called by muse, mutect2, varscan2
- OGDH | c.2451C>T p.F817= | Silent (SNP) | VAF 62/174 reads (36%) | catalogued as rs368953616; called by muse, mutect2, varscan2
- PCDHA11 | c.201G>A p.A67= | Silent (SNP) | VAF 271/489 reads (55%) | catalogued as rs1554162871, COSV56481801; called by muse, mutect2, varscan2
- PCDHGA11 | c.1671C>T p.N557= | Silent (SNP) | VAF 72/362 reads (20%) | called by muse, mutect2, varscan2
- RNF133 | c.489T>C p.I163= | Silent (SNP) | VAF 49/373 reads (13%) | called by muse, mutect2, varscan2
- RPH3A | c.1407C>T p.T469= (on ENST00000389385 / NM_001143854.2; = p.T465= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 113/255 reads (44%) | catalogued as rs749571110, COSV66990357; called by muse, mutect2, varscan2
- SCN10A | c.225C>T p.I75= | Silent (SNP) | VAF 141/266 reads (53%) | catalogued as rs771128445, COSV71861193; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC37A2 | c.666C>T p.G222= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs531000167; called by muse, mutect2, varscan2
- SOX14 | c.355C>T p.L119= | Silent (SNP) | VAF 52/208 reads (25%) | called by muse, mutect2, varscan2
- TEX36 | c.213C>T p.S71= | Silent (SNP) | VAF 99/244 reads (41%) | catalogued as rs1375609397, COSV64315679; called by muse, mutect2, varscan2
- TMEM200C | c.696G>A p.S232= | Silent (SNP) | VAF 87/87 reads (100%) | called by muse, mutect2, varscan2
- TNS1 | c.4485C>T p.G1495= | Silent (SNP) | VAF 69/153 reads (45%) | catalogued as rs373123074; called by muse, mutect2, varscan2
- TNXB | c.12057C>G p.A4019= (on ENST00000647633; = p.A3772= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/368 reads (16%) | called by muse, mutect2, varscan2
- UCHL1 | c.582G>A p.L194= | Silent (SNP) | VAF 108/438 reads (25%) | called by muse, mutect2, varscan2
- ZBTB46 | c.66C>T p.N22= | Silent (SNP) | VAF 49/400 reads (12%) | catalogued as rs371695871; called by muse, mutect2, varscan2
- ZFHX4 | c.8451C>T p.D2817= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs746820985, COSV50496015; called by muse, mutect2
- ARHGEF3 | c.130-33962G>A | Intron (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- DNAH10 | c.1816-2663C>T | Intron (SNP) | VAF 36/80 reads (45%) | catalogued as rs1207112631; called by muse, mutect2, varscan2
- GAB1 | c.1586-1660G>A | Intron (SNP) | VAF 81/191 reads (42%) | catalogued as rs779785762, COSV99528780; called by muse, mutect2, varscan2
- KRT77 | c.759-9G>A | Intron (SNP) | VAF 75/206 reads (36%) | catalogued as rs755222784, COSV59239176; called by muse, mutect2
- LRATD1 | c.*400C>T | 3'UTR (SNP) | VAF 79/163 reads (48%) | catalogued as rs1558254818; called by muse, mutect2, varscan2
- MIR34AHG | n.1909G>A | RNA (SNP) | VAF 108/444 reads (24%) | called by muse, mutect2, varscan2
- MIR373 | n.21G>A | RNA (SNP) | VAF 151/260 reads (58%) | catalogued as rs1236949062; called by muse, mutect2, varscan2
- MOG | c.593-111C>A | Intron (SNP) | VAF 201/445 reads (45%) | called by muse, mutect2, varscan2
- OGDHL | c.2320-12G>A | Intron (SNP) | VAF 71/145 reads (49%) | catalogued as rs187690070; called by muse, mutect2, varscan2
- PTPDC1 | c.83-653G>A | Intron (SNP) | VAF 181/265 reads (68%) | catalogued as rs781076359; called by muse, mutect2, varscan2
- RBMX | chrX:136872309 TCAG>A | 3'Flank (DEL) | VAF 19/145 reads (13%) | called by pindel, varscan2*
- SP140 | c.406+384T>C | Intron (SNP) | VAF 76/151 reads (50%) | catalogued as rs1429196650; called by muse, mutect2, varscan2
- TRPM3 | c.184-256714C>T | Intron (SNP) | VAF 40/211 reads (19%) | catalogued as COSV62702385; called by muse, mutect2, varscan2
- ZC3H7B | c.582+39A>T | Intron (SNP) | VAF 64/137 reads (47%) | called by muse, mutect2, varscan2
- ZEB2 | c.332-26A>C | Intron (SNP) | VAF 62/174 reads (36%) | called by muse, mutect2, varscan2
- ZNF875 | c.-243del | 5'UTR (DEL) | VAF 114/253 reads (45%) | called by mutect2, pindel, varscan2
